Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1ML, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1ML-01A (Primary Tumor).

ICD-0-3
Carcinoma, squamous cell, NOS 8070/3
Site: Cervix, NOS C53.9 2/24/11 *fw*

SURGICAL PATHOLOGY REPORT FINAL

Patient Name: [REDACTED]
Address: [REDACTED]
Gender: F
DOB: [REDACTED]

Service: Gynecology
Location: [REDACTED]
MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]

Accession #: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Accessioned: [REDACTED]
Reported: [REDACTED]

Physician(s): [REDACTED] M.D.

DIAGNOSIS:

UTERUS, CERVIX, BIOPSY
- INVASIVE SQUAMOUS CELL CARCINOMA (SEE COMMENT)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED] M.D., Ph.D.

***Report Electronically Reviewed and Signed Out By [REDACTED] M.D., Ph.D.

Microscopic Description and Comment:

Sections of the cervical biopsy show poorly differentiated squamous cell carcinoma. The carcinoma has a variety of morphologic patterns; in some areas it is well-differentiated and keratinizing, in other areas it is more basaloid, and in still other areas it shows a very high apoptotic rate with vague nuclear molding and rosette formations. Immunohistochemical stains show that the tumor is strongly positive for cytokeratin expression throughout, but negative for synaptophysin and chromogranin expression, results which exclude any neuroendocrine differentiation. [REDACTED]

History:

The patient is a [REDACTED] year old woman with cervical cancer. Operative procedure: Cervical biopsy.

Specimen(s) Received:

A: CERVIX

Gross Description:

The specimen is received in a formalin-filled container labeled [REDACTED] and "cervical biopsy." It consists of a single fragment of tan-brown tissue measuring 0.7 cm. Bisected, labeled A. Jar 0.

Reviewer Initials	[REDACTED]	

Source: NCI Genomic Data Commons file 2018c42e-fa74-4810-9b0d-032909e55dae (TCGA-C5-A1ML.D27AF07C-E69A-46DE-B1E6-4F494E3602B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).